Somatic mutation profile of tumor specimen TCGA-CZ-5457-01A (aliquot TCGA-CZ-5457-01A-01D-1501-10) from TCGA case TCGA-CZ-5457, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 62.3 years (22,763 days).
Specimen TCGA-CZ-5457-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e490c59-cc2e-48ba-b5ef-8e6df6c43b08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5457-11A (Solid Tissue Normal), aliquot TCGA-CZ-5457-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7272c1dc-63aa-4131-9c3b-9fcdb3f06378

The open-access MAF lists 80 somatic variants for this specimen: 66 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 2, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH5 | c.477A>T p.K159N | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV56449163; called by muse, mutect2, varscan2
- ALYREF | c.591G>T p.R197S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV58669274; called by muse, mutect2, varscan2
- ARID1B | c.2582T>A p.M861K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as COSV51682279; called by muse, mutect2, varscan2
- ATRX | c.5226G>T p.R1742S | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64883235; called by muse, mutect2, varscan2
- BCL2A1 | c.477A>T p.E159D | Missense Mutation (SNP) | VAF 98/455 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV51214178; called by muse, mutect2, varscan2
- CACNA1C | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.584); catalogued as COSV100223776, COSV59776167; called by muse, mutect2, varscan2
- CES2 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.327); catalogued as COSV57697935; called by muse, mutect2, varscan2
- CHEK2 | c.455T>G p.V152G (on ENST00000382580 / NM_001005735.2; = p.V109G on NM_007194.4) | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV60416167, COSV60426780; called by muse, mutect2, varscan2
- COL2A1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CD104461, COSV61534775; called by muse, mutect2, varscan2
- CUL3 | c.1791C>A p.F597L | Missense Mutation (SNP) | VAF 85/721 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as COSV52370964; called by muse, mutect2, varscan2
- CUL9 | c.6423G>A p.K2141= | Splice Region (SNP) | VAF 11/70 reads (16%) | catalogued as COSV52735187; called by muse, mutect2, varscan2
- DDX20 | c.1313-1G>A p.X438_splice | Splice Site (SNP) | VAF 68/271 reads (25%) | catalogued as COSV63778286; called by muse, mutect2, varscan2
- DLX3 | c.530T>A p.F177Y | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71547945; called by muse, mutect2
- DNAJC11 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs767604148, COSV53791208; called by muse, mutect2, varscan2
- DOCK2 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 108/394 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs1359183468, COSV56989909; called by muse, mutect2, varscan2
- DPT | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63191240; called by muse, mutect2, varscan2
- EGFL7 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV100451880, COSV58248855; called by muse, mutect2
- EIF4G2 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 141/427 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV60599249; called by muse, mutect2, varscan2
- ERBB4 | c.1058T>A p.I353N | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53526990; called by muse, mutect2, varscan2
- ERP27 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56764867; called by muse, mutect2
- FBN2 | c.3952A>T p.M1318L | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99324168; called by muse, mutect2, varscan2
- HCN1 | c.2634C>G p.D878E | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV100297614, COSV57538811; called by muse, mutect2
- HGS | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1183972450, COSV61270504; called by muse, mutect2, varscan2
- IFT140 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs769896754, COSV68501634; called by muse, mutect2, varscan2
- KCNA4 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60256161; called by muse, mutect2, varscan2
- KDR | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190064889, COSV55776975; called by muse, mutect2, varscan2
- KIF14 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV66264262; called by muse, mutect2, varscan2
- KMT2D | c.5719C>G p.L1907V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV56489496; called by muse, mutect2, varscan2
- LVRN | c.1170T>A p.D390E | Missense Mutation (SNP) | VAF 234/785 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.285); catalogued as COSV63498464; called by muse, mutect2, varscan2
- METTL16 | c.1073A>C p.K358T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV54016637; called by muse, mutect2, varscan2
- MRPS12 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99671041; called by muse, mutect2, varscan2
- MRTFB | c.3165C>G p.N1055K (on ENST00000571589 / NM_001365412.2; = p.N1005K on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV57962031; called by muse, mutect2
- MSH3 | c.1895A>C p.K632T | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54165438; called by muse, mutect2, varscan2
- MYO1F | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as rs1028019685, COSV57800498; called by muse, mutect2, varscan2
- NEUROD1 | c.883A>G p.K295E | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54551290, COSV99717065; called by muse, mutect2, varscan2
- PEG3 | c.4055A>G p.E1352G | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV55648678; called by muse, mutect2, varscan2
- PLAU | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV65642147; called by muse, mutect2, varscan2
- PLEKHJ1 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV55557331; called by muse, mutect2, varscan2
- REN | c.602A>T p.Q201L | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV65818476; called by muse, mutect2, varscan2
- RHBDF2 | c.2267T>A p.V756E | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51686515; called by muse, mutect2, varscan2
- RPS19BP1 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs756520743, COSV58180576; called by muse, mutect2, varscan2
- RYR1 | c.11858C>A p.A3953D | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62111778; called by muse, mutect2, varscan2
- SAMHD1 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53432800; called by muse, mutect2, varscan2
- SLC25A23 | c.1183T>A p.Y395N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51197848; called by muse, mutect2, varscan2
- SPCS1 | c.386T>G p.L129R (on ENST00000233025; = p.L62R on NM_014041.5) | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51778114; called by muse, mutect2, varscan2
- SPEG | c.3509T>G p.M1170R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56680295; called by muse, mutect2, varscan2
- TGM7 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746158461, COSV71772887; called by muse, mutect2, varscan2
- THBS1 | c.1862C>A p.P621H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52956073; called by muse, mutect2, varscan2
- TKTL2 | c.1238A>C p.N413T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV54921441; called by muse, mutect2, varscan2
- TNKS2 | c.2138T>C p.L713P | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65417084; called by muse, mutect2, varscan2
- TPST1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 31/228 reads (14%) | catalogued as COSV59177552; called by muse, mutect2, varscan2
- TRIO | c.6704A>T p.K2235I | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59992565; called by muse, mutect2, varscan2
- TULP4 | c.4288T>A p.W1430R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65581184; called by muse, mutect2, varscan2
- USP40 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 80/272 reads (29%) | catalogued as rs769149260, COSV52477865; called by muse, mutect2, varscan2
- VIPAS39 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 92/237 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV58942284; called by muse, mutect2, varscan2
- WFDC8 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 19/456 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV51490486, COSV51492075; called by muse, mutect2
- WRAP73 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV54563604; called by muse, mutect2, varscan2
- ITGB1 | c.327_344del p.D110_Q115del | In Frame Del (DEL) | VAF 85/584 reads (15%) | called by mutect2, pindel, varscan2
- LINS1 | c.1325del p.F442Sfs*2 | Frame Shift Del (DEL) | VAF 38/189 reads (20%) | called by mutect2, pindel, varscan2
- N4BP1 | c.1172del p.F391Sfs*49 | Frame Shift Del (DEL) | VAF 33/138 reads (24%) | called by mutect2, pindel, varscan2
- NME8 | c.388-1_389del p.X130_splice | Splice Site (DEL) | VAF 180/733 reads (25%) | called by mutect2, pindel, varscan2
- NUP214 | c.3620_3621del p.S1207Wfs*17 | Frame Shift Del (DEL) | VAF 124/447 reads (28%) | called by mutect2, pindel, varscan2
- NUP37 | c.619del p.E207Nfs*5 | Frame Shift Del (DEL) | VAF 95/422 reads (23%) | called by mutect2, pindel, varscan2
- PTH1R | c.213del p.A72Rfs*118 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel
- SLC9C2 | c.1402del p.I468Ffs*2 | Frame Shift Del (DEL) | VAF 148/620 reads (24%) | called by mutect2, varscan2
- ZFAT | c.3382del p.A1128Pfs*2 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- ADAM23 | c.864G>T p.V288= | Silent (SNP) | VAF 194/656 reads (30%) | catalogued as COSV52231319; called by muse, mutect2, varscan2
- CD300LB | c.93C>A p.S31= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV58725693, COSV58726669; called by muse, mutect2, varscan2
- CELF3 | c.25C>T p.L9= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV51885977; called by muse, mutect2, varscan2
- FIGN | c.276G>A p.S92= | Silent (SNP) | VAF 44/245 reads (18%) | catalogued as COSV60772022; called by muse, mutect2, varscan2
- ILDR2 | c.36C>T p.F12= | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as COSV54835709; called by muse, mutect2, varscan2
- JUNB | c.909C>T p.L303= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV56878938; called by muse, mutect2, varscan2
- KCTD2 | c.657C>G p.S219= | Silent (SNP) | VAF 117/346 reads (34%) | catalogued as COSV59369718; called by muse, mutect2
- LTB4R | c.282C>T p.H94= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV51868229; called by muse, mutect2, varscan2
- NUFIP2 | c.1338C>A p.I446= | Silent (SNP) | VAF 46/228 reads (20%) | catalogued as COSV56606263; called by muse, mutect2, varscan2
- OR13C2 | c.384C>T p.N128= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as rs1473073765, COSV73377803; called by muse, mutect2, varscan2
- PRKD3 | c.1620T>G p.V540= | Silent (SNP) | VAF 34/261 reads (13%) | catalogued as rs757719200, COSV52219033; called by muse, mutect2, varscan2
- TTYH3 | c.1452C>T p.P484= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV51863213; called by muse, mutect2, varscan2
- ZNF280D | c.2415T>G p.V805= | Silent (SNP) | VAF 69/362 reads (19%) | catalogued as COSV51001150; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827917 G>A | 3'Flank (SNP) | VAF 12/178 reads (7%) | catalogued as rs1556946187, COSV59428943; called by muse, mutect2
